Somatic mutation profile of tumor specimen C3N-00437-01 (aliquot CPT0012540006) from CPTAC case C3N-00437, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 69.8 years (25,495 days).
Specimen C3N-00437-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86998e1d-19b0-41c1-89e1-b2d0cc584ae3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00437-31 (Blood Derived Normal), aliquot CPT0012620002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25dba13e-630c-4562-ba48-303e2143a50c

The open-access MAF lists 62 somatic variants for this specimen: 37 protein-altering or splice-affecting, 16 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 16, Intron 4, Frame Shift Del 2, 5'Flank 2, RNA 1, Nonsense Mutation 1, 5'UTR 1, 3'UTR 1, Translation Start Site 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AARS1 | c.2503G>T p.A835S | Missense Mutation (SNP) | VAF 91/652 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs775304067; called by muse, mutect2, varscan2
- ADGRB1 | c.3352G>A p.V1118M | Missense Mutation (SNP) | VAF 24/411 reads (6%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.999); catalogued as rs781741541; called by muse, mutect2
- CYP7A1 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 24/416 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs149291486; called by muse, mutect2
- DVL1 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.616); catalogued as rs1375216646, COSV101127283; called by muse, mutect2, varscan2
- FBXO43 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 14/327 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV71053744; called by muse, mutect2
- GFOD1 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.195); catalogued as rs771312460, COSV64954663; called by muse, mutect2, varscan2
- IER3 | c.368C>T p.T123I | Missense Mutation (SNP) | VAF 51/354 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1014107448, COSV52543581, COSV52544563; called by muse, mutect2, varscan2
- LRRC4B | c.771G>T p.K257N | Missense Mutation (SNP) | VAF 39/362 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as COSV100975878; called by muse, mutect2, varscan2
- RBMXL3 | c.2825G>A p.R942H | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.84); catalogued as rs868941610, COSV57762046; called by muse, mutect2, varscan2
- VHL | c.419del p.L140Pfs*19 | Frame Shift Del (DEL) | VAF 36/357 reads (10%) | catalogued as CD983003, COSV56568261; called by mutect2, pindel, varscan2
- ADAMTS20 | c.5641G>A p.E1881K | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.089); called by muse, mutect2
- APOB | c.10781G>T p.W3594L | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.196); called by muse, mutect2
- BAP1 | c.338_350del p.S113Tfs*70 | Frame Shift Del (DEL) | VAF 38/371 reads (10%) | called by mutect2, pindel
- CACNB1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/229 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.258); called by muse, mutect2
- CFAP251 | c.1901A>C p.N634T | Missense Mutation (SNP) | VAF 51/423 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- DSC1 | c.2109_2116+11del p.X703_splice | Splice Site (DEL) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- FAM170B | c.468G>A p.M156I | Missense Mutation (SNP) | VAF 51/303 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- IGHM | c.64A>C p.S22R | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT tolerated (0.23); called by muse, mutect2, varscan2
- KLHL10 | c.282dup p.E95* | Frame Shift Ins (INS) | VAF 32/284 reads (11%) | called by mutect2, varscan2
- MBLAC2 | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOL12 | c.34G>T p.D12Y | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- OPTN | c.1565G>T p.G522V | Missense Mutation (SNP) | VAF 71/473 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- PARP9 | c.108G>C p.Q36H | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PCDHGC3 | c.328T>A p.L110M | Missense Mutation (SNP) | VAF 115/432 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- PDK2 | c.1064A>T p.D355V | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PHRF1 | c.1956A>C p.R652S (on ENST00000264555 / NM_001286581.2; = p.R651S on NM_020901.4) | Missense Mutation (SNP) | VAF 16/259 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PKDREJ | c.3274G>T p.D1092Y | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PRDM10 | c.1816C>A p.H606N | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- RNF34 | c.1307T>G p.L436R | Missense Mutation (SNP) | VAF 55/394 reads (14%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEPSECS | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 16/225 reads (7%) | called by muse, mutect2
- SETD2 | c.2727T>G p.D909E | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SI | c.228C>G p.N76K | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SLC25A53 | c.595A>T p.I199F | Missense Mutation (SNP) | VAF 15/213 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2
- TNC | c.5613A>T p.K1871N | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.827); called by muse, mutect2
- TTC23 | c.84C>A p.F28L | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF746 | c.855A>G p.I285M | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZNFX1 | c.3778C>T p.L1260F | Missense Mutation (SNP) | VAF 36/452 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- AFF2 | c.612C>G p.P204= | Silent (SNP) | VAF 26/264 reads (10%) | catalogued as COSV60678872; called by muse, mutect2
- AFF2 | c.948G>T p.G316= | Silent (SNP) | VAF 19/238 reads (8%) | catalogued as rs782587704; called by muse, mutect2
- C2orf81 | c.1110T>G p.S370= | Silent (SNP) | VAF 11/99 reads (11%) | called by muse, mutect2, varscan2
- CHEK2 | c.90C>A p.G30= | Silent (SNP) | VAF 29/194 reads (15%) | called by muse, mutect2, varscan2
- FAM104A | c.486C>T p.L162= | Silent (SNP) | VAF 58/530 reads (11%) | called by muse, varscan2
- IGFBP3 | c.181C>T p.L61= | Silent (SNP) | VAF 15/128 reads (12%) | called by muse, mutect2
- MAGEL2 | c.3141G>T p.V1047= | Silent (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- MAPT | c.576C>T p.A192= | Silent (SNP) | VAF 12/240 reads (5%) | called by muse, mutect2
- MORC2 | c.2970G>A p.T990= (on ENST00000397641 / NM_001303256.3; = p.T928= on NM_014941.3) | Silent (SNP) | VAF 30/520 reads (6%) | catalogued as rs781327828, COSV53203448; ClinVar: likely benign; called by muse, mutect2
- NXPE1 | c.474C>T p.D158= (on ENST00000424269; = p.D16= on NM_152315.5) | Silent (SNP) | VAF 15/216 reads (7%) | called by muse, mutect2
- PNPLA7 | c.3810C>T p.D1270= | Silent (SNP) | VAF 15/158 reads (9%) | catalogued as rs138586605; called by muse, mutect2
- PXDN | c.69G>A p.G23= | Silent (SNP) | VAF 48/610 reads (8%) | catalogued as rs995355920; called by muse, mutect2
- RRP7A | c.418C>T p.L140= | Silent (SNP) | VAF 25/303 reads (8%) | called by muse, mutect2, varscan2
- SEMA4G | c.2268C>T p.I756= (on ENST00000370250; = p.I761= on NM_017893.3) | Silent (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- TFAP2D | c.745T>C p.L249= | Silent (SNP) | VAF 12/142 reads (8%) | catalogued as rs549396552; called by muse, mutect2
- TFEC | c.312T>A p.I104= | Silent (SNP) | VAF 11/99 reads (11%) | called by muse, mutect2, varscan2
- CHST10 | c.-104+394_-104+395del | Intron (DEL) | VAF 49/241 reads (20%) | called by mutect2, pindel, varscan2
- CXCL5 | c.326+44G>C | Intron (SNP) | VAF 17/138 reads (12%) | called by muse, mutect2, varscan2
- FUT7 | chr9:137034775 C>A | 5'Flank (SNP) | VAF 56/460 reads (12%) | catalogued as rs371943249; called by muse, mutect2, varscan2
- LINC01956 | n.380G>A | RNA (SNP) | VAF 60/350 reads (17%) | catalogued as rs925586377; called by muse, mutect2, varscan2
- LY6E | chr8:143018218 C>T | 5'Flank (SNP) | VAF 129/450 reads (29%) | called by muse, mutect2, varscan2
- NFX1 | c.*14C>T | 3'UTR (SNP) | VAF 14/101 reads (14%) | called by muse, mutect2, varscan2
- NKRF | c.-17+2256C>A | Intron (SNP) | VAF 8/197 reads (4%) | called by muse, mutect2
- POLR2B | c.-18C>T | 5'UTR (SNP) | VAF 19/170 reads (11%) | called by muse, mutect2, varscan2
- SAMD13 | c.226-4374A>G | Intron (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2, varscan2
